Somatic mutation profile of tumor specimen TCGA-OE-A75W-01A (aliquot TCGA-OE-A75W-01A-12D-A32N-08) from TCGA case TCGA-OE-A75W, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Tail of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 75.8 years (27,684 days).
Specimen TCGA-OE-A75W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4914079d-9bbe-4dcc-8430-cb84f097546f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OE-A75W-10A (Blood Derived Normal), aliquot TCGA-OE-A75W-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7836f0b9-d868-418c-8459-f3164d967991

The open-access MAF lists 88 somatic variants for this specimen: 70 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 15, Nonsense Mutation 5, Frame Shift Del 2, Splice Region 2, RNA 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 68/153 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CRYBB1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 56/288 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs864309682, CM162357, COSV99315830; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 34/106 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.14678G>A p.R4893Q | Missense Mutation (SNP) | VAF 44/348 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs118192151, CM030713, CM061940, COSV100614374; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 139/338 reads (41%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC013477.1 | c.2551G>T p.E851* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV53653189; called by muse, mutect2
- ADGRL1 | c.3283G>A p.V1095I (on ENST00000340736 / NM_001008701.3; = p.V1090I on NM_014921.5) | Missense Mutation (SNP) | VAF 202/601 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs536482945, COSV61566268; called by muse, mutect2, varscan2
- ALG12 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 23/117 reads (20%) | PolyPhen possibly damaging (0.658); catalogued as rs952664215, COSV58207527; called by muse, mutect2, varscan2
- ANO6 | c.2284C>T p.P762S | Missense Mutation (SNP) | VAF 148/489 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.043); catalogued as COSV57659982; called by muse, mutect2, varscan2
- ARHGAP4 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782050839, COSV100603803; called by muse, mutect2, varscan2
- ATRNL1 | c.3227G>A p.C1076Y | Missense Mutation (SNP) | VAF 90/306 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100369302; called by muse, mutect2, varscan2
- BICRAL | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 125/423 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100017784; called by muse, mutect2, varscan2
- CBFA2T2 | c.1565A>T p.N522I | Missense Mutation (SNP) | VAF 133/526 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100656128; called by muse, mutect2, varscan2
- CCDC180 | c.4319A>G p.E1440G | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV100826546; called by muse, mutect2, varscan2
- CCN4 | c.609C>T p.F203= | Splice Region (SNP) | VAF 72/300 reads (24%) | catalogued as rs773458131, COSV51529381; called by muse, mutect2, varscan2
- CD33 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1315616154, COSV99220046; called by muse, mutect2
- CELF3 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1199276982, COSV99310012; called by muse, mutect2, varscan2
- CEP126 | c.1867A>T p.I623F | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV99680541; called by muse, mutect2, varscan2
- CEP63 | c.1710G>T p.K570N | Missense Mutation (SNP) | VAF 179/622 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.466); catalogued as COSV100132538; called by muse, mutect2
- CEP63 | c.1712C>T p.T571I | Missense Mutation (SNP) | VAF 180/627 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100132539; called by muse, mutect2
- CFAP58 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.38); catalogued as rs534892585, COSV100458738; called by muse, mutect2
- CXCR1 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 120/446 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.258); catalogued as rs56030518; called by muse, mutect2, varscan2
- DDC | c.652C>G p.R218G | Missense Mutation (SNP) | VAF 138/551 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs765007524, COSV100779111; called by muse, mutect2, varscan2
- DGKQ | c.2606T>C p.I869T | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV99297504; called by muse, mutect2, varscan2
- EGFLAM | c.560A>T p.K187M | Missense Mutation (SNP) | VAF 97/352 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as COSV100469696; called by muse, mutect2, varscan2
- F12 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99499413; called by muse, mutect2, varscan2
- FBN3 | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 11/353 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV54465154; called by muse, mutect2
- FSTL5 | c.2065T>A p.F689I | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as COSV100052559, COSV60209213; called by muse, mutect2, varscan2
- GOLGA1 | c.1966-1G>A p.X656_splice | Splice Site (SNP) | VAF 29/264 reads (11%) | catalogued as COSV99414499; called by muse, mutect2, varscan2
- GRIK2 | c.2617C>T p.R873C | Missense Mutation (SNP) | VAF 75/227 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs1049934499, COSV59753336; called by muse, mutect2, varscan2
- GRM8 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV100280618; called by muse, mutect2, varscan2
- HMCN1 | c.14726G>A p.R4909H | Missense Mutation (SNP) | VAF 97/363 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs148097981; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF20A | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 77/328 reads (23%) | catalogued as rs777958054, COSV50146110; called by muse, mutect2, varscan2
- LMAN1L | c.1360C>A p.P454T | Missense Mutation (SNP) | VAF 270/996 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs756762410, COSV100547544; called by muse, mutect2, varscan2
- LRP6 | c.3314T>C p.I1105T | Missense Mutation (SNP) | VAF 194/726 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.028); catalogued as COSV99742269; called by muse, mutect2, varscan2
- ME3 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 108/310 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs15926, COSV62775471; called by muse, mutect2, varscan2
- MICU3 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs774411224, COSV58846486; called by muse, mutect2, varscan2
- MOCS1 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 84/336 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100418429; called by muse, mutect2
- MPHOSPH8 | c.1096C>G p.Q366E | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.15); catalogued as COSV100824940; called by muse, mutect2, varscan2
- MYT1L | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.981); catalogued as COSV101218693; called by muse, mutect2, varscan2
- NADSYN1 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 42/473 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149234649, COSV100034471; called by muse, mutect2
- NCAPH | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 171/746 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769563241, COSV99545494; called by muse, mutect2, varscan2
- NELL2 | c.817A>T p.T273S | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.017); catalogued as COSV100418658; called by muse, mutect2, varscan2
- NIPA2 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 121/238 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.26); catalogued as rs201271184, COSV57410215; called by muse, mutect2, varscan2
- NRXN3 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 79/347 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as rs770583570; called by muse, mutect2, varscan2
- NSUN3 | c.15G>A p.L5= | Splice Region (SNP) | VAF 10/226 reads (4%) | catalogued as COSV58936143; called by muse, mutect2
- NTF3 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58417467; called by muse, mutect2
- OR10J1 | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 167/597 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV101419782; called by muse, mutect2, varscan2
- OR51A2 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 85/1383 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as rs1187550515, COSV100985001; called by muse, mutect2
- PCDH15 | c.4636G>T p.V1546F (on ENST00000644397 / NM_001354429.2; = p.V1495F on NM_001142769.3) | Missense Mutation (SNP) | VAF 138/683 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.485); catalogued as rs1015355645, COSV100902941; called by muse, mutect2, varscan2
- PCDHB8 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 235/1676 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.081); catalogued as COSV50758563, COSV99175569; called by muse, mutect2, varscan2
- PTDSS2 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 190/741 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as COSV100339017; called by muse, mutect2, varscan2
- RNF180 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 83/256 reads (32%) | catalogued as rs768721416, COSV56965471; called by muse, mutect2, varscan2
- SCN5A | c.5795C>T p.A1932V (on ENST00000333535 / NM_198056.3; = p.A1931V on NM_000335.5) | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs371194826; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SLC25A36 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 86/304 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.869); catalogued as COSV100148939; called by muse, mutect2, varscan2
- SMARCE1 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 124/490 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs1172017371, COSV52861729; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SOX14 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV100048034; called by muse, mutect2
- SPART | c.1700T>C p.V567A | Missense Mutation (SNP) | VAF 82/365 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100768549; called by muse, mutect2, varscan2
- SPATC1L | c.578C>T p.A193V (on ENST00000291672 / NM_001142854.2; = p.A39V on NM_032261.5) | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs781139512, COSV99385822; called by muse, mutect2, varscan2
- TASP1 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 43/661 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100534355; called by muse, mutect2
- TBX5 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 86/358 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as CM971436, COSV59858590; called by muse, mutect2, varscan2
- TENM2 | c.3392C>T p.A1131V (on ENST00000518659 / NM_001122679.2; = p.A899V on NM_001080428.3) | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.999); catalogued as rs779636997, COSV101317768, COSV69143717; called by muse, mutect2, varscan2
- TTN | c.5255G>A p.R1752H (on ENST00000591111; = p.R1706H on NM_003319.4) | Missense Mutation (SNP) | VAF 94/286 reads (33%) | PolyPhen probably damaging (0.998); catalogued as rs150737838, COSV59901601; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TUT4 | c.3119G>T p.R1040I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV57111494; called by muse, mutect2, varscan2
- VPS18 | c.1841G>A p.W614* | Nonsense Mutation (SNP) | VAF 22/556 reads (4%) | catalogued as COSV99592262, COSV99592433; called by muse, mutect2
- VPS25 | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 71/280 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV99519257; called by muse, mutect2, varscan2
- ZNF471 | c.1385A>T p.K462M | Missense Mutation (SNP) | VAF 42/678 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV100340345; called by muse, mutect2
- CFAP94 | c.221_224del p.L74* (on ENST00000320267 / NM_001352064.2; = p.L80* on NM_018272.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 32/166 reads (19%) | called by pindel, varscan2
- LUZP1 | c.596_603del p.Y199* | Frame Shift Del (DEL) | VAF 45/202 reads (22%) | called by mutect2, pindel, varscan2
- SEMA6D | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 15/483 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0.043); called by muse, mutect2
- ACRV1 | c.162T>C p.A54= | Silent (SNP) | VAF 84/321 reads (26%) | catalogued as COSV59755110; called by muse, mutect2, varscan2
- ARF1 | c.531C>T p.L177= | Silent (SNP) | VAF 26/336 reads (8%) | catalogued as COSV99683027; called by muse, mutect2
- L3MBTL2 | c.1902G>A p.P634= | Silent (SNP) | VAF 69/208 reads (33%) | catalogued as rs540563633, COSV99345629; called by muse, mutect2, varscan2
- LRIG3 | c.3045A>T p.L1015= | Silent (SNP) | VAF 16/354 reads (5%) | catalogued as COSV100292400; called by muse, mutect2
- MAST2 | c.1801C>T p.L601= | Silent (SNP) | VAF 137/304 reads (45%) | catalogued as COSV100787826; called by muse, mutect2, varscan2
- MECOM | c.219G>A p.T73= (on ENST00000468789 / NM_001105078.4; = p.T261= on NM_004991.4) | Silent (SNP) | VAF 220/819 reads (27%) | catalogued as rs150481592; called by muse, mutect2, varscan2
- NF1 | c.6780T>G p.S2260= (on ENST00000358273 / NM_001042492.3; = p.S2239= on NM_000267.3) | Silent (SNP) | VAF 76/926 reads (8%) | catalogued as COSV100645997; called by muse, mutect2
- NISCH | c.3402C>T p.V1134= | Silent (SNP) | VAF 79/577 reads (14%) | catalogued as rs750890542, COSV61900071; called by muse, mutect2, varscan2
- NLRP9 | c.1275C>T p.G425= | Silent (SNP) | VAF 199/716 reads (28%) | catalogued as rs1236523509, COSV60463433; called by muse, mutect2, varscan2
- NOTCH1 | c.1347C>T p.C449= | Silent (SNP) | VAF 102/396 reads (26%) | catalogued as rs1455628051, COSV99484959; called by muse, mutect2, varscan2
- NOTCH3 | c.6612G>A p.P2204= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs752030208, COSV54647033; called by muse, mutect2
- PGLYRP3 | c.756G>T p.V252= | Silent (SNP) | VAF 41/131 reads (31%) | catalogued as COSV99319470, COSV99319923; called by muse, mutect2, varscan2
- SDK1 | c.2637A>G p.E879= | Silent (SNP) | VAF 61/256 reads (24%) | catalogued as COSV101268736; called by muse, mutect2, varscan2
- SIPA1L3 | c.4458C>T p.V1486= | Silent (SNP) | VAF 66/332 reads (20%) | catalogued as rs569236464, COSV99727233; called by muse, mutect2, varscan2
- TNFAIP8L1 | c.171G>A p.Q57= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV100542347; called by muse, mutect2, varscan2
- AC024940.1 | n.3644T>C | RNA (SNP) | VAF 98/379 reads (26%) | called by muse, mutect2, varscan2
- NTNG1 | c.1087+10893T>A | Intron (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100903396; called by muse, mutect2, varscan2
- SSPOP | n.14921G>C | RNA (SNP) | VAF 26/85 reads (31%) | catalogued as COSV100946969; called by muse, mutect2, varscan2
